Somatic mutation profile of tumor specimen MMRF_2216_1_BM_CD138pos (aliquot MMRF_2216_1_BM_CD138pos_T1_KHS5U_L08834) from MMRF case MMRF_2216, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.3 years (30,785 days).
Specimen MMRF_2216_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078193b7-f987-444a-910b-2a3168b0e292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2216_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2216_1_PB_WBC_C3_KHS5U_L08807; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c387012a-157c-4dc2-b27e-21282832a3b5

The open-access MAF lists 149 somatic variants for this specimen: 47 protein-altering or splice-affecting, 26 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 35, Silent 26, Intron 22, 5'UTR 7, 3'Flank 6, 5'Flank 4, RNA 2, Frame Shift Del 2, Splice Region 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 45/105 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- B3GNT6 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); catalogued as COSV62829237; called by muse, mutect2, varscan2
- C1orf94 | c.1418C>T p.T473M (on ENST00000488417 / NM_001134734.2; = p.T283M on NM_032884.5) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs140728068; called by muse, mutect2, varscan2
- CEACAM4 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1555801574; called by muse, mutect2, varscan2
- CMYA5 | c.6062T>C p.L2021S | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs577593375; called by muse, mutect2, varscan2
- CSRNP3 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs753115769, COSV58776425; called by muse, mutect2, varscan2
- ENOSF1 | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); catalogued as rs201382707, COSV99075506; called by muse, varscan2
- GARNL3 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368892230, COSV100149990; called by muse, mutect2, varscan2
- GCFC2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV58082699; called by muse, mutect2, varscan2
- INPP5E | c.1741A>T p.T581S | Missense Mutation (SNP) | VAF 180/263 reads (68%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs1473447000; called by muse, mutect2, varscan2
- KRT28 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs748981632; called by muse, mutect2, varscan2
- NPTX2 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377548219; called by muse, mutect2, varscan2
- NTRK3 | c.1304C>A p.A435E | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58142987; called by muse, mutect2, varscan2
- PRUNE2 | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1328486618; called by muse, mutect2, varscan2
- RESF1 | c.490A>T p.M164L | Missense Mutation (SNP) | VAF 118/222 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771487904; called by muse, mutect2, varscan2
- RNF113B | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773255110; called by muse, mutect2, varscan2
- RTL6 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs1236930707, COSV57979973; called by muse, mutect2, varscan2
- SEMA4C | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100561051; called by muse, mutect2, varscan2
- SGCG | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317594969; called by muse, mutect2, varscan2
- SRRM4 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.073); catalogued as rs750601249, COSV57412746, COSV99939730; called by muse, mutect2, varscan2
- TRMT2A | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1242151140; called by muse, mutect2, varscan2
- XPO5 | c.3313C>T p.R1105C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1467134868; called by muse, mutect2, varscan2
- ZNF525 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 90/377 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs758153460; called by muse, mutect2, varscan2
- AFF1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 116/120 reads (97%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD24 | c.3441A>C p.*1147Cext*73 | Nonstop Mutation (SNP) | VAF 91/158 reads (58%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ESYT3 | c.2235T>C p.I745= | Splice Region (SNP) | VAF 133/260 reads (51%) | called by muse, mutect2, varscan2
- FAT3 | c.4748C>G p.S1583* | Nonsense Mutation (SNP) | VAF 69/224 reads (31%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by mutect2, varscan2
- ISCU | c.247G>T p.G83W (on ENST00000311893 / NM_213595.4; = p.G58W on NM_014301.4) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- KDELR2 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.35); called by muse, varscan2
- KDELR2 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, varscan2
- MCM3AP | c.5669A>T p.D1890V | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED13 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MTM1 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 98/99 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYDGF | c.197del p.T66Ifs*14 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- RBM14 | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- REM1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RYR2 | c.14663G>T p.C4888F | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SH2B1 | c.1037T>A p.V346D | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TCL1A | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD5 | c.104A>C p.Y35S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC2 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- THOC2 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TMX4 | c.835del p.E279Kfs*29 | Frame Shift Del (DEL) | VAF 161/403 reads (40%) | called by mutect2, pindel, varscan2
- TRPM5 | c.1493C>A p.A498D | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF646 | c.4115G>A p.S1372N | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- ABLIM1 | c.2136A>G p.E712= | Silent (SNP) | VAF 6/170 reads (4%) | called by muse, mutect2
- ADCY7 | c.2955C>T p.S985= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs1175752107; called by muse, mutect2
- ATRAID | c.228C>G p.L76= (on ENST00000611786; = p.L21= on NM_001170795.3) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs1263956061; called by muse, mutect2, varscan2
- CDHR2 | c.3168G>A p.P1056= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as rs267600559, COSV56142793; called by muse, mutect2, varscan2
- CDO1 | c.390T>C p.C130= | Silent (SNP) | VAF 90/343 reads (26%) | called by muse, mutect2, varscan2
- CFAP74 | c.4227G>A p.E1409= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1557981434; called by mutect2, varscan2
- CHD5 | c.3243G>A p.E1081= | Silent (SNP) | VAF 86/181 reads (48%) | called by muse, mutect2, varscan2
- COL5A3 | c.1704T>C p.F568= | Silent (SNP) | VAF 59/297 reads (20%) | called by muse, mutect2, varscan2
- DGAT1 | c.726C>T p.S242= | Silent (SNP) | VAF 72/155 reads (46%) | called by muse, mutect2, varscan2
- ERVV-1 | c.1284G>A p.T428= | Silent (SNP) | VAF 98/308 reads (32%) | catalogued as rs1661940; called by muse, mutect2, varscan2
- HSD11B1 | c.651C>T p.L217= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2
- ITGAX | c.609C>T p.F203= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as rs771349695, COSV51643085; called by muse, mutect2, varscan2
- KCNIP1 | c.9C>T p.A3= | Silent (SNP) | VAF 165/559 reads (30%) | catalogued as rs778210728; called by muse, mutect2, varscan2
- KDELR2 | c.255C>T p.T85= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, varscan2
- LCT | c.3822C>T p.N1274= | Silent (SNP) | VAF 81/147 reads (55%) | catalogued as rs200090526, COSV51555608; called by muse, mutect2, varscan2
- NPAS1 | c.1683G>A p.P561= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs1456191591; called by muse, mutect2, varscan2
- NUP188 | c.4095C>T p.P1365= | Silent (SNP) | VAF 52/233 reads (22%) | catalogued as rs747496972; called by muse, mutect2, varscan2
- OBSCN | c.11757A>G p.T3919= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs1558302925, COSV99474622; called by muse, mutect2
- RSPH6A | c.1038C>A p.G346= | Silent (SNP) | VAF 131/688 reads (19%) | called by muse, mutect2, varscan2
- SIM1 | c.1293C>T p.D431= | Silent (SNP) | VAF 68/125 reads (54%) | catalogued as rs139715467, COSV53495466; called by muse, mutect2, varscan2
- SNX31 | c.801G>C p.R267= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- SULF1 | c.327C>T p.N109= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs370128603; called by muse, mutect2, varscan2
- TEKT1 | c.654G>A p.L218= | Silent (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- VMO1 | c.579C>T p.N193= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs764585650, COSV54497819; called by muse, mutect2, varscan2
- WNK2 | c.5253G>A p.Q1751= (on ENST00000297954 / NM_001282394.1; = p.Q1714= on NM_006648.3) | Silent (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- ZNF319 | c.39G>T p.P13= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs755117561; called by muse, mutect2, varscan2
- AMER2 | chr13:25165259 G>C | 3'Flank (SNP) | VAF 108/421 reads (26%) | called by muse, mutect2, varscan2
- ANXA11 | c.*3954A>T | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- ATP6V1C1 | c.*2461del | 3'UTR (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- BSCL2 | chr11:62707420 C>T | 5'Flank (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- CA3 | c.351+72A>G | Intron (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- CFAP92 | c.*1020T>G | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- CYP2B6 | c.*2G>A | 3'UTR (SNP) | VAF 45/170 reads (26%) | called by muse, mutect2, varscan2
- DBNDD2 | c.159+34C>A | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- DNAH3 | c.118-4237G>C | Intron (SNP) | VAF 64/153 reads (42%) | called by muse, varscan2
- DNAH3 | c.118-4310G>T | Intron (SNP) | VAF 56/120 reads (47%) | catalogued as COSV99769537; called by muse, varscan2
- ELK4 | c.*6901T>C | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- EPB41L5 | c.*693dup | 3'UTR (INS) | VAF 44/112 reads (39%) | called by mutect2, varscan2
- ETV1 | chr7:13891411 G>A | 3'Flank (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- FOXP1 | c.181-18036G>T | Intron (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- GALE | c.*290T>C | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- GGNBP2 | c.-106-30G>A | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- GPR137B | c.837+13G>A | Intron (SNP) | VAF 29/68 reads (43%) | catalogued as rs369137317; called by muse, mutect2, varscan2
- GRTP1 | c.182-17G>A | Intron (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- GSTM3 | c.*2892T>G | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- IDH3A | c.91-567dup | Intron (INS) | VAF 12/35 reads (34%) | called by mutect2, varscan2
- IGF1R | c.*5832G>T | 3'UTR (SNP) | VAF 53/149 reads (36%) | called by muse, mutect2, varscan2
- INHBA | c.*2551G>A | 3'UTR (SNP) | VAF 37/83 reads (45%) | catalogued as rs148319568; called by muse, mutect2, varscan2
- IQCK | c.-580G>A | 5'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as rs982510771; called by muse, mutect2, varscan2
- ISL1 | chr5:51383225 del A | 5'Flank (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel*, varscan2
- KBTBD6 | c.*1931C>G | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2266+6046G>A | Intron (SNP) | VAF 16/27 reads (59%) | catalogued as rs928427372; called by muse, mutect2, varscan2
- LARGE2 | c.*180C>T | 3'UTR (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- LMO2 | c.-111G>A | 5'UTR (SNP) | VAF 20/68 reads (29%) | catalogued as rs1240731044; called by muse, mutect2, varscan2
- LTB | c.162+169G>A | Intron (SNP) | VAF 34/75 reads (45%) | catalogued as COSV53001174; called by muse, mutect2, varscan2
- MCF2L | c.3279-21G>A | Intron (SNP) | VAF 48/75 reads (64%) | catalogued as rs755158791; called by muse, mutect2, varscan2
- MEIS1 | c.-268A>T | 5'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- MYL5 | c.3+259G>A | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- NKX2-1 | chr14:36520137 C>T | 5'Flank (SNP) | VAF 102/194 reads (53%) | catalogued as rs749414192, COSV100702024; called by muse, mutect2, varscan2
- NKX3-1 | c.*1179dup | 3'UTR (INS) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- NPY1R | c.*125C>T | 3'UTR (SNP) | VAF 97/189 reads (51%) | catalogued as COSV99649135; called by muse, mutect2, varscan2
- NRXN1 | c.-331G>A | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- OR51S1 | c.*16G>C | 3'UTR (SNP) | VAF 96/330 reads (29%) | called by muse, mutect2, varscan2
- OTUD3 | c.*4808G>A | 3'UTR (SNP) | VAF 85/151 reads (56%) | catalogued as rs1286552397; called by muse, mutect2, varscan2
- PCDH15 | c.*3344C>T | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- PCDH7 | c.*44G>A | 3'UTR (SNP) | VAF 16/22 reads (73%) | called by muse, mutect2, varscan2
- PCM1 | c.5512-95G>T | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- PCNX2 | c.4077-1052G>A | Intron (SNP) | VAF 63/116 reads (54%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-12600T>A | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- PLA2G2F | c.*96G>A | 3'UTR (SNP) | VAF 8/13 reads (62%) | catalogued as rs908788405; called by muse, mutect2, varscan2
- POU2F3 | c.-29dup | 5'UTR (INS) | VAF 84/133 reads (63%) | catalogued as rs756729035; called by mutect2, varscan2
- PPP2R2D | c.*2642G>C | 3'UTR (SNP) | VAF 108/225 reads (48%) | called by muse, mutect2, varscan2
- PRDM16 | c.*3521G>A | 3'UTR (SNP) | VAF 93/194 reads (48%) | catalogued as rs571685031; called by muse, mutect2, varscan2
- RIMS3 | c.*5704G>A | 3'UTR (SNP) | VAF 31/62 reads (50%) | catalogued as rs578052560; called by muse, mutect2, varscan2
- RPS4XP21 | n.698C>T | RNA (SNP) | VAF 11/303 reads (4%) | called by muse, mutect2
- SH3KBP1 | c.*1451G>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1665+59C>A | Intron (SNP) | VAF 55/87 reads (63%) | called by muse, mutect2, varscan2
- SNX3 | c.-92C>G | 5'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.976T>G | RNA (SNP) | VAF 40/69 reads (58%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20317018 ins T | 3'Flank (INS) | VAF 56/138 reads (41%) | called by mutect2, pindel, varscan2
- SPEG | c.4447+87C>G | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SPHKAP | c.*1555C>T | 3'UTR (SNP) | VAF 40/63 reads (63%) | catalogued as rs532739001, COSV60877610; called by muse, mutect2, varscan2
- SPIN1 | c.*707G>T | 3'UTR (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- SPIN1 | c.*2487T>G | 3'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66180598 ins T | 3'Flank (INS) | VAF 29/108 reads (27%) | catalogued as rs990042323; called by mutect2, varscan2
- STAG3 | c.2132+27T>G | Intron (SNP) | VAF 51/123 reads (41%) | called by muse, mutect2, varscan2
- SUDS3 | c.*3193C>G | 3'UTR (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2
- SUPT16H | c.*978G>A | 3'UTR (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- TMEM198 | c.*405G>C | 3'UTR (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- TP53INP1 | c.*3140C>T | 3'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.374+298C>T | Intron (SNP) | VAF 27/29 reads (93%) | called by muse, mutect2, varscan2
- TRDN | c.*829C>T | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- TRIM33 | c.*3296T>C | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as rs1293394760; called by muse, mutect2, varscan2
- TTC16 | c.1853-8dup | Intron (INS) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- TXNDC16 | c.*1490C>A | 3'UTR (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- UBAP2L | chr1:154271153 A>C | 3'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- USP34 | c.-142G>T | 5'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2
- VMA21 | chrX:151396710 T>C | 5'Flank (SNP) | VAF 66/66 reads (100%) | called by muse, varscan2
- YIF1A | c.642-167C>T | Intron (SNP) | VAF 78/111 reads (70%) | called by muse, mutect2, varscan2
- ZNF362 | c.*798C>T | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- ZNF493 | c.*145C>A | 3'UTR (SNP) | VAF 104/424 reads (25%) | called by muse, mutect2, varscan2
- ZNF793 | chr19:37548296 G>T | 3'Flank (SNP) | VAF 37/191 reads (19%) | called by muse, mutect2, varscan2
